Gene-level copy-number profile of tumor specimen TCGA-CZ-4858-01A from TCGA case TCGA-CZ-4858, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 39.3 years (14,343 days).
Specimen TCGA-CZ-4858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.576879fd-a58b-4347-ab97-0e845d9010d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-4858-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/13985db0-fe43-451f-bde6-b7b6c41ba223

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 57; copy number 2: 16,546; copy number 3: 20,268; copy number 4: 16,942; copy number 5: 1,827; copy number 6: 3,367; copy number 7: 798.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CZ-4858-01): tumor purity 0.46, ploidy 3.31, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,700,142, 6 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1.
- chr9:8,858,127–9,442,380, 4 genes: PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 798 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:143,265,222–143,848,485, 1 gene, copy number 7 (within-gene range 6–7): SLC9A9.
- chr3:143,381,338–182,368,256, 560 genes, copy number 7 (broad region; genes not listed).
- chr3:187,368,385–198,222,513, 237 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 57. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
